Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040027-09A.1 (aliquot TARGET-15-SJMPAL040027-09A.1-01D) from TARGET case TARGET-15-SJMPAL040027, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-15-SJMPAL040027-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 589995b5-faff-471f-9881-ee1e18e7faa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040027-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040027-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af0f4196-10e7-4bf3-9470-b39a8baa9b64

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 1, 5'UTR 1, 3'UTR 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 128/138 reads (93%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, varscan2
- CPT1B | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs368302579; called by muse, mutect2, varscan2
- GLYAT | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1565053353; called by muse, varscan2
- KIF12 | c.869G>T p.S290I (on ENST00000640217; = p.S152I on NM_138424.1) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65118582; called by muse, mutect2
- RHOD | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs749309126; called by muse, varscan2
- ZBED1 | c.1882G>T p.V628L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV58132844; called by muse, mutect2
- DHX57 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXT1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- FAM117B | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.465); called by muse, mutect2
- IPP | c.748G>T p.V250F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- LRRC45 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- USP9X | c.2878-2A>C p.X960_splice | Splice Site (SNP) | VAF 28/28 reads (100%) | called by muse, mutect2, varscan2
- VPS51 | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF57 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTS18 | c.1473G>A p.A491= | Silent (SNP) | VAF 100/228 reads (44%) | catalogued as rs148669189, COSV51400093; called by muse, mutect2, varscan2
- EFCAB6 | c.4068C>T p.N1356= | Silent (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- KRT20 | c.804G>T p.L268= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- PCDHA11 | c.123C>T p.H41= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as rs1428940405, COSV56551586; called by muse, mutect2, varscan2
- TUBA3C | c.717G>A p.T239= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs397839852; called by muse, mutect2, varscan2
- ATG2A | c.*232C>T | 3'UTR (SNP) | VAF 3/31 reads (10%) | catalogued as rs970230004, COSV63475690; called by muse, mutect2
- MACF1 | c.220+21181C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SPINK9 | c.-13C>A | 5'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100930724; called by muse, mutect2
